TCGA case TCGA-B8-5550 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/59278f79-4f42-4d1c-9007-3958486042fc

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 71.0 years (25,937 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 3.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 72.9 years (26,631 days); Days to diagnosis: 694 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (5 entries)
- Days to follow up: 197 days; Disease response: Tumor Free.
- Days to follow up: 434 days (1.2 years); Disease response: Tumor Free.
- Day 694 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,476 days (4.0 years); Disease response: With Tumor.
- ECOG performance status: 3; Timepoint: Post Adjuvant Therapy.

Molecular and laboratory tests
- Calcium: Normal.
- Platelets: Normal.
- Leukocytes: Normal.
- Hemoglobin: Normal.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 20; Tobacco smoking onset year: 1970.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B8-5550-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.7; Intermediate dimension: 0.5; Shortest dimension: 0.4.
  Slide TCGA-B8-5550-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25.
  Slide TCGA-B8-5550-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-B8-5550-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B8-5550-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Tobacco smoking history indicator: 2.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome at TCGA followup: Progressive Disease; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; Performance status timing: Post Secondary Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,476 days; disease-specific survival: no event (censored), 1,476 days; disease-free interval: event (new tumor event after initially disease-free), 694 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 694 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B8-5550-01A-01D-1530-01): tumor purity 0.4, ploidy 2.17, whole-genome doublings 0.
